Gene-level copy-number profile of tumor specimen AP-U8MP-M6 from APOLLO case AP-U8MP, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen AP-U8MP-M6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bd20ea8f-8783-47a4-be86-82da6aec91ca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-U8MP-8M (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/d36d692b-7142-490d-9945-fa374bb0eb4a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 15,189; copy number 2: 39,877; copy number 3: 3,070; copy number 4: 159; copy number 5: 48; copy number 6: 24; copy number 7: 16.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr22:15,282,557–15,492,564, 6 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 88 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:13,690,331–16,617,058, 35 genes, copy number 5–7 (within-gene range 4–7): DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1.
- chr5:19,471,296–20,575,873, 4 genes, copy number 5: CDH18, AC093303.1, AC094103.1, CDH18-AS1.
- chr10:73,674,287–75,236,030, 49 genes, copy number 5–6 (within-gene range 1–6): AGAP5, BMS1P4-AGAP5, BMS1P4, AC022400.4, RNA5SP320, BMS1P4, GLUD1P3, DUSP8P5, AC022400.3, AC022400.6, SEC24C, AC022400.7, FUT11, CHCHD1, ZSWIM8, AC022400.8, ZSWIM8-AS1, AC022400.5, NDST2, CAMK2G, AC022400.1, AC022400.2, PLAU, C10orf55, VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1.

Autosomal genes at a single copy (total copy number 1): 12,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
